Somatic mutation profile of tumor specimen TCGA-FS-A1ZJ-06A (aliquot TCGA-FS-A1ZJ-06A-12D-A197-08) from TCGA case TCGA-FS-A1ZJ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.1 years (28,524 days).
Specimen TCGA-FS-A1ZJ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70805beb-cb0d-4d8e-a620-8fc270153cfb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZJ-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZJ-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75554d8d-cb8c-495b-9749-349731add27a

The open-access MAF lists 67 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 40, Silent 19, Splice Site 3, Frame Shift Del 2, In Frame Ins 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAG1 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs199474685, CM010072, COSV55024826; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHDC1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99898777; called by mutect2, varscan2
- AP3D1 | c.3079-1G>A p.X1027_splice | Splice Site (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100642887, COSV61428537; called by muse, varscan2
- C10orf71 | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60507911; called by mutect2, varscan2
- C12orf50 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs758153766, COSV53895360; called by muse, mutect2, varscan2
- CBLN2 | c.331C>A p.R111S | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV54051276, COSV54052083; called by muse, mutect2, varscan2
- CCDC51 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV56489848; called by muse, mutect2, varscan2
- CDH23 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV54935028, COSV99824257; called by muse, mutect2, varscan2
- CNGA2 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV61704587, COSV61705359; called by muse, mutect2, varscan2
- CPS1 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51810862; called by muse, mutect2, varscan2
- CTNNBL1 | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs202016331, COSV63744901, COSV63744911; called by muse, mutect2, varscan2
- DCC | c.2539C>A p.P847T | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59103732; called by muse, mutect2, varscan2
- DDX53 | c.323C>G p.A108G | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.403); catalogued as COSV60069090; called by muse, mutect2, varscan2
- DEFB113 | c.73del p.T25Qfs*? | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs758917875, COSV104398000; called by mutect2, pindel, varscan2
- EXD1 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV100153461; called by muse, varscan2
- FMO1 | c.1334C>G p.A445G | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV61445848; called by muse, mutect2
- FUT9 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as COSV56147465; called by muse, mutect2, varscan2
- GABRG1 | c.510T>G p.I170M | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54954421; called by muse, varscan2
- GGN | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV53057046; called by muse, mutect2, varscan2
- GPR139 | c.1003A>T p.I335F | Missense Mutation (SNP) | VAF 95/114 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV58502983; called by muse, mutect2, varscan2
- HABP4 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV64514860; called by muse, mutect2, varscan2
- ICE2 | c.1592C>G p.T531S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV55031539; called by muse, mutect2, varscan2
- IK | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV99346945; called by muse, mutect2
- IL18RAP | c.1364G>A p.R455K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51824550, COSV51826064; called by muse, mutect2, varscan2
- IL4I1 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV62010067; called by mutect2, varscan2
- KCNJ5 | c.949C>G p.Q317E | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV57966279; called by muse, mutect2, varscan2
- KIT | c.1507_1508insTTGCCC p.Y503delinsFAH | In Frame Ins (INS) | VAF 42/104 reads (40%) | catalogued as COSV55398383, COSV55416186, COSV99852927; called by pindel, varscan2
- KRT35 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs753519912, COSV55842898; called by mutect2, varscan2
- LONP1 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV62261785; called by muse, mutect2, varscan2
- LRRTM4 | c.830C>G p.P277R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139767, COSV69140303; called by muse, mutect2, varscan2
- LUZP2 | c.639C>A p.C213* | Nonsense Mutation (SNP) | VAF 52/68 reads (76%) | catalogued as COSV61204656, COSV61221538; called by muse, mutect2, varscan2
- MMP17 | c.1051G>C p.G351R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62179422; called by muse, mutect2, varscan2
- PI4KB | c.933T>A p.S311R (on ENST00000368873 / NM_001369623.1; = p.S323R on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV55017633; called by muse, mutect2, varscan2
- PRSS48 | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 110/218 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV71613860; called by muse, mutect2, varscan2
- PSME3 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs778805863, COSV53199277; called by muse, mutect2, varscan2
- PTPDC1 | c.296A>T p.E99V (on ENST00000375360 / NM_177995.3; = p.E151V on NM_152422.4) | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV56623354; called by muse, mutect2, varscan2
- SIDT1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369727245, COSV53502905; called by mutect2, varscan2
- SLC5A4 | c.478-2A>G p.X160_splice | Splice Site (SNP) | VAF 20/22 reads (91%) | catalogued as COSV56670580; called by muse, mutect2, varscan2
- SPAST | c.1537-2A>G p.X513_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as CS000469, COSV59514565; called by muse, mutect2, varscan2
- SPZ1 | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 152/353 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV57063296; called by muse, mutect2, varscan2
- SRF | c.451A>C p.I151L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54838627; called by muse, mutect2, varscan2
- STRIP2 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV50804450; called by muse, mutect2, varscan2
- TRPC6 | c.2619T>A p.D873E | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); catalogued as COSV60255025; called by muse, mutect2, varscan2
- VSTM2A | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV56494354, COSV56496321; called by muse, mutect2, varscan2
- ZNF217 | c.2951T>A p.L984Q | Missense Mutation (SNP) | VAF 65/87 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as COSV56597342; called by muse, mutect2, varscan2
- ZNF630 | c.232T>A p.Y78N | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52096435; called by muse, mutect2, varscan2
- BTAF1 | c.1083_1085del p.D361del | In Frame Del (DEL) | VAF 24/34 reads (71%) | called by pindel, varscan2
- TOGARAM1 | c.3063del p.Y1021* | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- AR | c.807C>T p.Y269= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs767555714, COSV65957236; called by muse, mutect2, varscan2
- BRD9 | c.879T>C p.S293= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs755283945, COSV60246765; called by muse, mutect2, varscan2
- CSNK1G2 | c.816C>T p.R272= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs752677240, COSV55336974; called by mutect2, varscan2
- CYP4F11 | c.126T>C p.Y42= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs762483147, COSV56127136; called by muse, varscan2
- DST | c.3279C>G p.P1093= (on ENST00000361203 / NM_001374722.1; = p.P767= on NM_001723.6) | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV55015782; called by muse, mutect2, varscan2
- DST | c.1950A>G p.E650= (on ENST00000361203 / NM_001374722.1; = p.E324= on NM_001723.6) | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV55015815; called by muse, mutect2, varscan2
- GNAS | c.1731C>T p.S577= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs554838821, COSV58335638; called by mutect2, varscan2
- IL18RAP | c.1473C>T p.I491= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as COSV51826087; called by muse, varscan2
- IL18RAP | c.1641C>T p.P547= | Silent (SNP) | VAF 72/195 reads (37%) | catalogued as COSV51826138; called by muse, varscan2
- LY75 | c.1620C>T p.Y540= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV55105838; called by muse, mutect2, varscan2
- MAP3K15 | c.3396C>T p.I1132= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV58830474; called by muse, mutect2, varscan2
- NEURL1 | c.549C>T p.N183= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as rs142246980; called by muse, mutect2, varscan2
- NUP62CL | c.213G>C p.V71= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV65235951; called by muse, mutect2, varscan2
- OR11A1 | c.525T>A p.I175= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV65821009; called by muse, mutect2, varscan2
- PRPH2 | c.507C>T p.N169= | Silent (SNP) | VAF 67/219 reads (31%) | catalogued as rs143096101, CD033226; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1341G>C p.G447= | Silent (SNP) | VAF 51/66 reads (77%) | catalogued as rs139031897; called by muse, mutect2, varscan2
- RAVER1 | c.888C>T p.F296= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV53345634; called by muse, varscan2
- WFS1 | c.858G>A p.L286= | Silent (SNP) | VAF 93/419 reads (22%) | catalogued as rs748652556, COSV56989152; called by muse, mutect2, varscan2
- ZNF592 | c.2904C>T p.A968= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV55437006; called by muse, mutect2, varscan2
